Gene-level copy-number profile of tumor specimen TCGA-EB-A5UL-06A from TCGA case TCGA-EB-A5UL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.7 years (26,178 days).
Specimen TCGA-EB-A5UL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.cdfb9a0c-a289-4f35-8fb3-5097625c4854.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A5UL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a4a96bbb-6820-4f62-9da6-5217e33f5401

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,419; copy number 2: 20,317; copy number 3: 20,325; copy number 4: 13,327; copy number 5: 2,686; copy number 6: 582; copy number 7: 98; copy number 8: 57; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A5UL-06A-11D-A30W-01): tumor purity 0.46, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 156 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:66,003,839–72,583,535, 76 genes, copy number 7–8 (broad region; genes not listed).
- chr3:128,462,439–130,678,155, 80 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,419. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
